Somatic mutation profile of tumor specimen TCGA-XM-A8R9-01A (aliquot TCGA-XM-A8R9-01A-31D-A423-09) from TCGA case TCGA-XM-A8R9, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type A, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 71.7 years (26,176 days).
Specimen TCGA-XM-A8R9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74170112-bc63-4cbf-a576-c8ce39c5dd97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XM-A8R9-10A (Blood Derived Normal), aliquot TCGA-XM-A8R9-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8fa7ff87-bb51-4b56-a1cc-a017e70b12a4

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, In Frame Ins 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 18/426 reads (4%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2
- FCHO2 | c.1093A>T p.N365Y | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs1192072487; called by muse, mutect2
- PLXNB2 | c.3525G>A p.V1175= | Splice Region (SNP) | VAF 5/34 reads (15%) | catalogued as rs1431685062, COSV63781469; called by muse, mutect2, varscan2
- BDP1 | c.1122_1123insTTT p.V374_L375insF | In Frame Ins (INS) | VAF 9/77 reads (12%) | called by mutect2, pindel, varscan2
- GPR52 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MRGPRX3 | c.377G>A p.W126* | Nonsense Mutation (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- R3HDM1 | c.2570A>T p.Y857F | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.068); called by muse, mutect2
- SDAD1 | c.1576A>G p.I526V | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL4A6 | c.3741C>A p.G1247= | Silent (SNP) | VAF 13/94 reads (14%) | called by muse, mutect2, varscan2
- PKNOX1 | c.1215G>A p.E405= | Silent (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2
